Somatic mutation profile of tumor specimen ALCH-B2RB-TTP1-B (aliquot ALCH-B2RB-TTP1-B-1-0-D-A81V-36) from ALCHEMIST case ALCH-B2RB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 58.3 years (21,281 days).
Specimen ALCH-B2RB-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d9ed8b2-df50-4149-8737-57d418df7676.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2RB-NB1-A (Blood Derived Normal), aliquot ALCH-B2RB-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7203b7c7-109b-433a-9435-0b2985a65d8a

The open-access MAF lists 214 somatic variants for this specimen: 150 protein-altering or splice-affecting, 42 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 42, Intron 13, Nonsense Mutation 13, Frame Shift Del 4, RNA 3, 5'UTR 3, Splice Site 2, 3'UTR 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV51003724; called by muse, mutect2
- ARHGAP39 | c.2093C>T p.A698V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1448366853; called by muse, mutect2, varscan2
- ATAD2 | c.1237delinsCT p.D413Lfs*3 | Frame Shift Ins (INS) | VAF 20/161 reads (12%) | catalogued as COSV54880494; called by pindel, varscan2*
- CASC3 | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs372980819; called by muse, mutect2, varscan2
- CCR1 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140711017; called by muse, mutect2, varscan2
- CDH17 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1039325781; called by muse, mutect2, varscan2
- DNAH7 | c.11547C>G p.S3849R | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1196114400; called by muse, mutect2, varscan2
- DTNA | c.1555C>G p.R519G | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52011927; called by muse, mutect2, varscan2
- EPX | c.1099C>A p.R367S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV99836210, COSV99836870; called by mutect2, varscan2
- F13B | c.1125G>T p.E375D | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.799); catalogued as COSV100803188; called by muse, mutect2, varscan2
- FAM171B | c.409A>C p.I137L | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.191); catalogued as COSV100489042; called by muse, mutect2, varscan2
- FAM24A | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs1235954887, COSV100925072; called by muse, mutect2, varscan2
- FLT1 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56741279; called by muse, mutect2, varscan2
- FSHR | c.37A>C p.S13R | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.225); catalogued as COSV58622573; called by muse, mutect2, varscan2
- GDPD5 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.743); catalogued as rs1319847200, COSV61126564; called by muse, mutect2, varscan2
- HERC2 | c.6868G>T p.A2290S | Missense Mutation (SNP) | VAF 16/251 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs978465712; called by muse, mutect2
- IFTAP | c.387G>T p.E129D | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as COSV57559671; called by muse, mutect2, varscan2
- IGKJ5 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 10/152 reads (7%) | catalogued as rs746860352; called by muse, mutect2
- IRF7 | c.1148G>A p.R383H (on ENST00000397566; = p.R370H on NM_001572.5) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1311553182; called by muse, varscan2
- ITGA8 | c.1346G>T p.G449V | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV65229946; called by muse, mutect2, varscan2
- ITK | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV70062710; called by muse, mutect2
- KEAP1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV50280201, COSV50642330; called by muse, varscan2
- KNSTRN | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1056073891, COSV51113063; called by muse, varscan2
- LAMA1 | c.5963G>T p.R1988M | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV67544094; called by muse, mutect2, varscan2
- LRRTM4 | c.213C>A p.N71K | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV69140795; called by muse, mutect2, varscan2
- MBD5 | c.3695A>G p.N1232S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.199); catalogued as COSV68698186; called by muse, mutect2
- MS4A1 | c.440T>A p.L147* | Nonsense Mutation (SNP) | VAF 15/83 reads (18%) | catalogued as rs538978795, COSV61942332; called by muse, mutect2, varscan2
- MS4A5 | c.440G>T p.C147F | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55740480; called by muse, mutect2
- MYBBP1A | c.2254G>A p.V752M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750821486; called by muse, mutect2, varscan2
- MYO1C | c.2252G>A p.R751Q (on ENST00000648651 / NM_001080779.2; = p.R716Q on NM_033375.5) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs762768584; called by muse, mutect2, varscan2
- MYO3A | c.4714A>T p.I1572F | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs774660855; called by muse, mutect2, varscan2
- MYO5A | c.4850T>C p.L1617S | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs767223291; called by muse, mutect2
- NEUROD6 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV51770230; called by muse, mutect2, varscan2
- OR8G1 | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100422277; called by muse, mutect2, varscan2
- PAX6 | c.771G>T p.W257C | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD166760, CM073259; called by muse, mutect2, varscan2
- PYDC2 | c.130del p.Q44Rfs*4 | Frame Shift Del (DEL) | VAF 40/213 reads (19%) | catalogued as rs1348240779; called by mutect2, pindel, varscan2
- RTN4 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as rs143644566; called by muse, mutect2, varscan2
- SDCCAG8 | c.1942C>T p.Q648* | Nonsense Mutation (SNP) | VAF 36/257 reads (14%) | catalogued as rs367572249; called by muse, mutect2, varscan2
- SFMBT2 | c.914A>G p.K305R | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as COSV62808301; called by muse, mutect2
- SHISA7 | c.1050C>A p.H350Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1232520521; called by muse, varscan2
- SHOX | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV61861149; called by mutect2, varscan2
- SMARCC1 | c.1579G>T p.A527S | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.585); catalogued as COSV54381350; called by muse, mutect2, varscan2
- TEX13C | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs758447529; called by muse, mutect2, varscan2
- TMEM214 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs1421501386, COSV104380854; called by muse, varscan2
- TNKS | c.908A>G p.Q303R | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1317404003; called by muse, mutect2
- TTBK2 | c.1903G>C p.D635H | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV51157908; called by muse, mutect2, varscan2
- ZFAT | c.3329C>T p.A1110V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs773605523, COSV64736169; called by mutect2, varscan2
- ZNF804A | c.859G>T p.D287Y | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100169596, COSV99043240; called by muse, mutect2, varscan2
- ADGRL3 | c.1989G>T p.M663I (on ENST00000506720 / NM_001322402.2; = p.M595I on NM_015236.6) | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- AMPH | c.1096G>C p.A366P | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANK2 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 40/320 reads (13%) | called by muse, mutect2, varscan2
- APBA2 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- APOBEC4 | c.150G>C p.Q50H | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2
- AQR | c.2381A>T p.Q794L | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2
- ARHGAP35 | c.876G>A p.W292* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- ARHGAP39 | c.2092G>T p.A698S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ARMCX2 | c.1363C>A p.L455M | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- ATAD2B | c.1097G>C p.R366T | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.396); called by muse, mutect2
- BBS9 | c.1406G>T p.C469F | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- BTNL9 | c.66C>A p.F22L | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- BTNL9 | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.211); called by muse, mutect2
- C1orf162 | c.461C>A p.T154K | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- C1orf167 | c.3526G>A p.V1176M | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.192); called by muse, varscan2
- CAPN6 | c.53A>C p.Q18P | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCDC146 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CNN2 | c.252+1G>T p.X84_splice | Splice Site (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- COL1A2 | c.3518G>T p.W1173L | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); called by muse, varscan2
- COL28A1 | c.2869G>A p.E957K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- CSMD3 | c.4201A>G p.R1401G (on ENST00000297405 / NM_001363185.1; = p.R1297G on NM_052900.3) | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); called by muse, mutect2
- CWF19L2 | c.1221A>T p.K407N | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPT | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DYRK1B | c.757A>T p.S253C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EDDM3A | c.308T>A p.L103H | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EGFL8 | c.871A>T p.N291Y | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- EGFLAM | c.845C>G p.A282G | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPHA5 | c.568G>C p.D190H | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERCC3 | c.1730+1G>T p.X577_splice | Splice Site (SNP) | VAF 23/199 reads (12%) | called by muse, mutect2, varscan2
- EVX2 | c.65G>C p.G22A | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- FMNL2 | c.2075C>G p.T692R | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- FSIP2 | c.15439G>A p.D5147N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- FYCO1 | c.2068G>A p.A690T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXB7 | c.540G>T p.Q180H | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXC11 | c.811C>A p.L271M | Missense Mutation (SNP) | VAF 14/265 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HR | c.485G>T p.C162F | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HTATSF1 | c.1417A>T p.K473* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- IDO2 | c.766G>A p.V256I (on ENST00000389060; = p.V269I on NM_194294.2) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.361); called by muse, mutect2
- IGHV5-51 | c.181G>C p.G61R | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- KMT2D | c.5968G>T p.E1990* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- L3MBTL3 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2
- LHX5 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LPA | c.3001T>C p.Y1001H | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- LRRC74A | c.632G>T p.C211F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MAK | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MAP3K13 | c.1577C>A p.P526H | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2
- MAP4K3 | c.941G>C p.R314T | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.023); called by muse, mutect2
- MASP1 | c.2029C>A p.R677S | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- MBD5 | c.3941T>A p.L1314Q | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- MEIOC | c.2678_2679del p.V893Gfs*25 | Frame Shift Del (DEL) | VAF 18/120 reads (15%) | called by pindel, varscan2
- MFSD2A | c.1399G>T p.G467W (on ENST00000372809 / NM_001136493.3; = p.G454W on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTARC2 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MYH1 | c.2056G>T p.G686C | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYH13 | c.4342A>C p.K1448Q | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.929); called by muse, mutect2
- NCAPD3 | c.662A>T p.K221M | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2
- NEXMIF | c.1579A>C p.K527Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOTCH4 | c.5108C>A p.T1703K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10T2 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- OR11H2 | c.58G>C p.G20R (on ENST00000556246; = p.G31R on NM_001197287.1) | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- OR2G3 | c.792C>A p.D264E | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2
- OR4P4 | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- OR52N1 | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- OR52N1 | c.511T>A p.C171S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR8D1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 19/157 reads (12%) | called by muse, mutect2, varscan2
- OR8J3 | c.443C>A p.T148K | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- OTUD5 | c.1260G>T p.Q420H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2
- PAPPA2 | c.1660C>A p.L554M | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PARP14 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 32/192 reads (17%) | called by muse, mutect2, varscan2
- PAX7 | c.1280C>A p.A427D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- PCDH11X | c.1153G>T p.V385L | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- PLET1 | c.270A>T p.R90S | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- POU3F4 | c.535C>A p.H179N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PPARG | c.460C>T p.H154Y (on ENST00000287820 / NM_015869.5; = p.H124Y on NM_005037.7) | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP4R4 | c.2269G>A p.V757I | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PSMB3 | c.590C>A p.T197N | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); called by muse, mutect2
- PSME4 | c.2434C>T p.Q812* | Nonsense Mutation (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- PUM3 | c.1913G>C p.G638A | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- QRFPR | c.1147G>C p.V383L | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RASGRF1 | c.433C>A p.H145N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SCN7A | c.1507A>G p.M503V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SGCE | c.851G>T p.C284F (on ENST00000647096; = p.C248F on NM_003919.3) | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIPA1L1 | c.3696_3700del p.H1233Ifs*44 | Frame Shift Del (DEL) | VAF 15/132 reads (11%) | called by mutect2, pindel, varscan2
- SLFN12 | c.1531G>C p.D511H | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- SLITRK4 | c.383T>A p.L128H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- STEAP1B | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- STEAP4 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2
- TFIP11 | c.2046G>A p.W682* | Nonsense Mutation (SNP) | VAF 33/263 reads (13%) | called by muse, mutect2, varscan2
- TMEM155 | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TMEM161A | c.733C>G p.P245A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TNKS2 | c.1333C>T p.H445Y | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); called by muse, mutect2
- TRAV3 | c.207C>A p.Y69* | Nonsense Mutation (SNP) | VAF 37/217 reads (17%) | called by muse, mutect2, varscan2
- TRGV11 | c.192del p.K65Rfs*7 | Frame Shift Del (DEL) | VAF 15/131 reads (11%) | called by mutect2, pindel, varscan2
- TRPM1 | c.451G>C p.A151P | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2
- USP13 | c.1676G>C p.S559T | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP34 | c.8242G>C p.G2748R | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USP6 | c.2035G>T p.D679Y | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBED9 | c.2161C>G p.P721A | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZIC1 | c.524C>A p.P175Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ZNF726 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 24/264 reads (9%) | called by muse, mutect2
- ZNF99 | c.1694A>G p.Y565C | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZPBP | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ADAMTS12 | c.2139A>T p.G713= | Silent (SNP) | VAF 26/71 reads (37%) | called by muse, varscan2
- AKAP6 | c.363C>T p.I121= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs1434902249; called by muse, mutect2
- ARHGAP31 | c.2049G>A p.Q683= | Silent (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2, varscan2
- C9orf64 | c.390T>G p.V130= | Silent (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- CAPN6 | c.1719C>A p.T573= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV60695334; called by muse, mutect2, varscan2
- CCNB3 | c.1497G>T p.G499= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV52069913; called by muse, mutect2, varscan2
- CLVS2 | c.285C>A p.G95= | Silent (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- CRACD | c.3273G>T p.T1091= | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2, varscan2
- DBR1 | c.918A>G p.P306= | Silent (SNP) | VAF 19/127 reads (15%) | called by muse, mutect2, varscan2
- DENND5A | c.1044T>A p.S348= | Silent (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- DLGAP2 | c.156G>A p.P52= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs777663374; called by muse, mutect2, varscan2
- DPPA4 | c.471C>A p.S157= | Silent (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- EMCN | c.684T>C p.N228= | Silent (SNP) | VAF 15/76 reads (20%) | called by muse, mutect2, varscan2
- GUCY2C | c.1746C>A p.G582= | Silent (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- HECW1 | c.525C>A p.P175= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV67841382; called by muse, mutect2, varscan2
- HK2 | c.2682G>A p.E894= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as rs1267193851; called by muse, mutect2, varscan2
- IL1RAP | c.1098C>A p.A366= | Silent (SNP) | VAF 8/203 reads (4%) | called by muse, mutect2
- INPP5D | c.3342C>T p.A1114= (on ENST00000445964 / NM_001017915.3; = p.A1113= on NM_005541.5) | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs765450380; called by muse, varscan2
- INTU | c.1338G>C p.A446= | Silent (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- KCNQ3 | c.750G>T p.L250= | Silent (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- KIF23 | c.2011C>A p.R671= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as CM1314893; called by muse, mutect2
- LRRC8A | c.483G>T p.L161= | Silent (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- MYO1E | c.1854G>C p.V618= | Silent (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- NALCN | c.2985C>T p.R995= | Silent (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2, varscan2
- NALCN | c.1350C>A p.L450= | Silent (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2
- NWD2 | c.4677G>C p.R1559= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- OR10S1 | c.276C>T p.P92= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV73342685; called by muse, mutect2, varscan2
- OR2M3 | c.228C>A p.T76= | Silent (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- PCSK1 | c.1104T>A p.A368= | Silent (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- PDE8B | c.384G>T p.T128= | Silent (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- PNPLA5 | c.1110G>T p.P370= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV53375979; called by mutect2, varscan2
- POLR3GL | c.522G>A p.E174= | Silent (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- RAG2 | c.1374C>T p.C458= | Silent (SNP) | VAF 34/190 reads (18%) | catalogued as COSV57557046; called by muse, mutect2, varscan2
- SGCD | c.495T>C p.V165= (on ENST00000435422 / NM_001128209.2; = p.V166= on NM_000337.5) | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- SLC26A5 | c.927G>A p.L309= | Silent (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- SLITRK2 | c.762G>T p.V254= | Silent (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- SOHLH2 | c.516T>A p.T172= | Silent (SNP) | VAF 24/183 reads (13%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.1308T>C p.S436= | Silent (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- SYNE3 | c.243C>T p.P81= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs775669417, COSV62078813; called by mutect2, varscan2
- UBTFL1 | c.459C>T p.F153= | Silent (SNP) | VAF 12/239 reads (5%) | catalogued as rs1478295071; called by muse, mutect2
- USP6NL | c.504C>G p.S168= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as COSV53213973; called by muse, mutect2
- ZNF574 | c.414G>A p.Q138= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, varscan2
- AC109583.1 | c.-1521G>A | 5'UTR (SNP) | VAF 3/27 reads (11%) | catalogued as rs1439450461; called by muse, varscan2
- AL353804.6 | chrX:73827690 G>T | 3'Flank (SNP) | VAF 62/232 reads (27%) | called by muse, mutect2, varscan2
- BAZ2B | c.2832+12C>T | Intron (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- CAMKMT | c.377-72750G>A | Intron (SNP) | VAF 11/88 reads (13%) | called by muse, varscan2
- CBWD2 | c.154+1054A>G | Intron (SNP) | VAF 22/334 reads (7%) | called by muse, mutect2
- CSMD3 | c.178+59878T>C | Intron (SNP) | VAF 34/221 reads (15%) | called by muse, mutect2, varscan2
- ELMO1 | c.1438-24398C>A | Intron (SNP) | VAF 4/40 reads (10%) | called by muse, varscan2
- FAM172BP | n.604C>T | RNA (SNP) | VAF 9/157 reads (6%) | called by muse, mutect2
- FCRL5 | c.307+681C>T | Intron (SNP) | VAF 9/88 reads (10%) | catalogued as rs1034898118; called by muse, mutect2, varscan2
- HNRNPL | c.881-28G>C | Intron (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- IGKV1D-42 | c.-8G>T | 5'UTR (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2, varscan2
- LINC00452 | n.612-3418G>T | Intron (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- MAP3K19 | c.3222+353C>A | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2
- MBD5 | c.2845+300C>A | Intron (SNP) | VAF 8/44 reads (18%) | catalogued as rs551782728; called by muse, mutect2, varscan2
- OR2L1P | n.452T>G | RNA (SNP) | VAF 17/215 reads (8%) | called by muse, mutect2
- PAGE1 | c.*23C>G | 3'UTR (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- RUNX1T1 | c.1280-3933C>A | Intron (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- SERGEF | c.448-1436G>C | Intron (SNP) | VAF 7/188 reads (4%) | called by muse, mutect2
- SNORD115-29 | n.72C>A | RNA (SNP) | VAF 14/145 reads (10%) | catalogued as rs374847172; called by muse, mutect2, varscan2
- VAPB | c.*2610C>A | 3'UTR (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- XKR6 | c.764+137736A>G | Intron (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- ZNF81 | c.-121G>T | 5'UTR (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
